MMRF case MMRF_1261 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7ddaf10e-a09f-4d8d-9c2d-0fad5e83a13d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 1,110 days (3.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.2 years (20,888 days); ISS stage: II; Days to last known disease status: 1,110 days (3.0 years); Days to last follow up: 1,110 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 232 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 202 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 246 days; Days to treatment end: 246 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 351 days; Days to treatment end: 615 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 364 days; Days to treatment end: 615 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 638 days (1.7 years); Days to treatment end: 757 days (2.1 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 793 days (2.2 years); Days to treatment end: 909 days (2.5 years).
   Treatment given: Therapeutic agents: Dexamethasone + Other + Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 932 days (2.6 years); Days to treatment end: 1,060 days (2.9 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 1,077 days (2.9 years); Days to treatment end: 1,098 days (3.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,110.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 613 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Beta 2 Microglobulin 3.66 µg/mL; Hemoglobin 5.95 mmol/L; Leukocytes 4.48 ×10⁹/L; Absolute Neutrophil 3.06 ×10⁹/L; Platelets 473 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Glucose 6.44 mmol/L.
- Day 86 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.718 mg/dL; Hemoglobin 7.81 mmol/L; Leukocytes 4.29 ×10⁹/L; Absolute Neutrophil 3.13 ×10⁹/L; Platelets 312 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.79 mmol/L.
- Day 162 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Hemoglobin 8.87 mmol/L; Leukocytes 3.31 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 370 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.55 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 3.74 mmol/L.
- Day 235: Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Hemoglobin 6.39 mmol/L; Leukocytes 3.7 ×10⁹/L; Platelets 33 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.18 mmol/L; Glucose 5.28 mmol/L.
- Day 351 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.55 mg/dL; Hemoglobin 8 mmol/L; Leukocytes 4.04 ×10⁹/L; Absolute Neutrophil 2.31 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.89 mmol/L.
- Day 434 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.828 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 4.15 ×10⁹/L; Absolute Neutrophil 2.48 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 5.61 mmol/L.
- Day 546 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Hemoglobin 8.56 mmol/L; Leukocytes 3.12 ×10⁹/L; Absolute Neutrophil 1.66 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.53 mmol/L; Albumin 45 g/L; Total Protein 7.6 g/dL; Glucose 4.62 mmol/L.
- Day 638 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 82.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 8.91 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 7.22 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.03 ×10⁹/L; Absolute Neutrophil 1.84 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.17 mmol/L.
- Day 722 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 10.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.167 mg/dL; Immunoglobulin G 4.23 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 8.39 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.17 ×10⁹/L; Absolute Neutrophil 3.22 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 3.85 mmol/L.
- Day 806 (ECOG 1): Lactate Dehydrogenase 12.6 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.12 ×10⁹/L; Absolute Neutrophil 2.64 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 904 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 205 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.688 mg/dL; Lactate Dehydrogenase 14.3 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.16 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.6 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.56 mmol/L.
- Day 988 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 48.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 4.9 mmol/L.
- Day 1,077 (ECOG 1): Immunoglobulin G 4.32 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 12.3 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.23 ×10⁹/L; Absolute Neutrophil 4.71 ×10⁹/L; Platelets 384 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.93 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 6.22 mmol/L.

Other clinical attributes
- Day -6: Weight: 56 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1261_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1261_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
